Surgical pathology report (de-identified scan), TCGA case TCGA-19-2625, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2625-01A (Primary Tumor).

[page 1 of 2]
2625
SURGICAL PATHOLOGY REPORT
Addendum Present

FINAL DIAGNOSIS

A.-C. RIGHT FRONTAL TUMOR, BIOPSIES:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: Resection specimens will be dictated as an addendum.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. Touch Imprint/Microscopic: Malignant tumor with abundant necrosis - Metastatic v. GBM.
B. Touch Imprint/Microscopic: Consistent with GBM (Glioblastoma Multiforme).
Intraoperative diagnosis is transmitted to [REDACTED] at [REDACTED]
C. Touch Imprint: GBM (Glioblastoma Multiforme).
Diagnosis transmitted to [REDACTED] at [REDACTED]

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Status: Signed Out

Addendum Diagnosis

D., E. RIGHT FRONTAL LOBE AND WHITE MATTER, PARTIAL REMOVAL:
-- CEREBRAL CORTEX AND WHITE MATTER CONTAINING INFILTRATING HIGH GRADE
ASTROCYTOMA, CONSISTENT WITH DERIVATION FROM GLIOBLASTOMA MULTIFORME.

F. RIGHT FRONTAL TUMOR FOR PERMANENT SECTIONS, REMOVAL:
-- GLIOBLASTOMA MULTIFORME (TWO GRADE IV).

Electronically Signed Out By [REDACTED]

Clinical History:

r frontal tumor

[page 2 of 2]
Specimens Submitted As:

A:FRONTAL TUMOR R
B:R FRONTAL TUMOR
C:TUMOR B4
D:RIGHT FRONTAL LOBE TUMOR
E:R FRONTAL WHITE MATTER
F:R FRONTAL PERMAMENT TUMOR

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name, number and "right frontal tumor", are multiple fragments of red-tan, soft tissue that measure in aggregate 0.3 x 0.2 x 0.1 cm. Representative sections are submitted for frozen section and touch imprint diagnosis. The specimen is entirely submitted in two cassettes.

B: Received fresh, for intraoperative consultation, labelled with the patient's, number and "right frontal tumor", are multiple fragments of pink-tan, soft tissue that measure in aggregate 2.2 x 1.4 x 0.3 cm. Representative sections are submitted for frozen section and touch preparation. The specimen was entirely submitted.

C: Received fresh, for intraoperative consultation, labelled with the patient's name, number and "tumor #4", are multiple fragments of red-tan, soft tissue that measure in aggregate 1.8 x 1.8 x 0.2 cm. A touch preparation was made. The specimen is entirely submitted in one cassette.

D: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#4 frontal lobe", are multiple irregular, opaque white to tan brown, soft, cerebriform tissue fragments measuring in aggregate 8.8 x 6.4 x 3.5 cm. Representative sections are submitted in three cassettes.

E: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#3-perm WM", are two irregular, opaque white to tan brown, soft, cerebriform tissue fragments measuring in aggregate 3.5 x 3.5 x 1.6 cm. Representative sections are submitted in three cassettes.

F: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "perm tumor", are multiple irregular, opaque white to tan-brown, soft, cerebriform tissue fragments measuring in aggregate 5.5 x 4.7 x 1.4 cm. Representative sections are submitted in three cassettes.

Summary of Cassettes:

Specimen	Label	Site
A	1	frozen section residue
	2	remainder of specimen
B	1	frozen section residue
	2	remainder of specimen

Source: NCI Genomic Data Commons file f75d3016-75d4-404a-8733-963b65db7ff7 (TCGA-19-2625.4F37276D-3579-49DB-AE54-5644B2F2F92F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).